FM case AD8019 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/e50f32ce-aee2-4007-8767-eee1f0d6123d

Female, 67.5 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
